Somatic mutation profile of tumor specimen C3L-07957-03 (aliquot CPT0533410006_1) from CPTAC case C3L-07957, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G1; Age at diagnosis: 65.3 years (23,840 days).
Specimen C3L-07957-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8dc2cddd-298c-42cb-946d-15f21869b438.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07957-31 (Blood Derived Normal), aliquot CPT0533540002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dbc2ee71-b680-4eba-92fc-49c4c652078b

The open-access MAF lists 101 somatic variants for this specimen: 78 protein-altering or splice-affecting, 19 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 19, Nonsense Mutation 4, Intron 3, Frame Shift Del 2, Splice Site 1, Frame Shift Ins 1, Splice Region 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB3 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 114/393 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.64); catalogued as rs1057519893, COSV57246387, COSV57246465, COSV57253558; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GNAS | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 95/391 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs121913495, CM158823, COSV55670349, COSV55671845; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MTOR | c.5930C>A p.T1977K | Missense Mutation (SNP) | VAF 10/286 reads (3%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs587777893, COSV63868784, COSV63869673, COSV63869920; ClinVar: not provided; called by muse, mutect2
- APOL2 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 39/344 reads (11%) | SIFT tolerated (0.81); PolyPhen benign (0.133); catalogued as rs760928601, COSV50772910; called by muse, mutect2, varscan2
- ARFRP1 | c.562G>A p.V188M | Missense Mutation (SNP) | VAF 45/371 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs750436290, COSV53926356; called by muse, mutect2, varscan2
- ARHGEF12 | c.1825C>T p.R609C | Missense Mutation (SNP) | VAF 35/440 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1051039253; called by muse, mutect2
- BX255925.3 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 42/288 reads (15%) | SIFT deleterious, low confidence (0.01); catalogued as rs995619805; called by muse, mutect2, varscan2
- CACNA2D3 | c.1936G>A p.D646N | Missense Mutation (SNP) | VAF 67/438 reads (15%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.997); catalogued as COSV55546323; called by muse, mutect2
- CCT8L2 | c.507G>C p.M169I | Missense Mutation (SNP) | VAF 52/516 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0.059); catalogued as COSV63462828; called by muse, mutect2, varscan2
- CNTNAP2 | c.1343C>A p.S448Y | Missense Mutation (SNP) | VAF 37/337 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.543); catalogued as COSV62195484; called by muse, mutect2
- COL1A1 | c.466G>A p.G156R | Missense Mutation (SNP) | VAF 33/293 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs781774588; called by muse, mutect2, varscan2
- CRAMP1 | c.1321G>A p.V441M | Missense Mutation (SNP) | VAF 87/680 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.08); catalogued as rs571857474, COSV51966113, COSV99246430; called by muse, mutect2, varscan2
- CUX2 | c.1850C>T p.S617L | Missense Mutation (SNP) | VAF 46/341 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs774991259, COSV55622878; called by muse, mutect2, varscan2
- DCAF12L1 | c.541T>A p.S181T | Missense Mutation (SNP) | VAF 89/390 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780712210; called by muse, mutect2, varscan2
- DPYS | c.1367C>T p.T456M | Missense Mutation (SNP) | VAF 60/443 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs113309169; called by muse, mutect2, varscan2
- FNIP1 | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 41/314 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1411219564, COSV57196972; called by muse, mutect2, varscan2
- FOXL2 | c.1095C>A p.S365R | Missense Mutation (SNP) | VAF 49/370 reads (13%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.068); catalogued as COSV100374726; called by muse, mutect2, varscan2
- GBA3 | c.1381C>T p.R461* | Nonsense Mutation (SNP) | VAF 26/372 reads (7%) | catalogued as rs538670192, COSV101545479, COSV101545563; called by muse, mutect2
- GNA15 | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 73/444 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); catalogued as rs1245473019; called by muse, mutect2, varscan2
- GPX6 | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 41/365 reads (11%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.009); catalogued as COSV100724757; called by muse, mutect2, varscan2
- GRM1 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 58/392 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); catalogued as rs553512718, COSV51109088; called by muse, mutect2, varscan2
- KCNQ4 | c.1981G>A p.D661N | Missense Mutation (SNP) | VAF 79/572 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs1171470293; called by muse, mutect2, varscan2
- KIF19 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 45/411 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs377150875, COSV100739040; called by muse, mutect2, varscan2
- KLHL29 | c.889C>T p.R297W | Missense Mutation (SNP) | VAF 151/595 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1014456936, COSV56022545; called by muse, mutect2, varscan2
- LAMC3 | c.4255C>T p.R1419W | Missense Mutation (SNP) | VAF 52/388 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs147688904; called by muse, mutect2, varscan2
- MAP3K4 | c.4796C>T p.S1599L | Missense Mutation (SNP) | VAF 37/331 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.183); catalogued as COSV62330283; called by muse, mutect2, varscan2
- MYH9 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 37/313 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53381589; called by muse, mutect2, varscan2
- NEB | c.3235G>T p.A1079S | Missense Mutation (SNP) | VAF 34/251 reads (14%) | SIFT tolerated (1); PolyPhen probably damaging (0.995); catalogued as COSV51420115; called by muse, mutect2, varscan2
- NFIX | c.1121C>T p.T374M | Missense Mutation (SNP) | VAF 71/571 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as rs1193070672, COSV62179868; called by muse, mutect2, varscan2
- NKD1 | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 38/324 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.571); catalogued as rs753850728; called by muse, varscan2
- OR6K2 | c.583G>A p.V195I | Missense Mutation (SNP) | VAF 54/348 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.013); catalogued as rs369203639, COSV100656859, COSV62743146; called by muse, mutect2, varscan2
- PCDH10 | c.1313G>A p.R438Q | Missense Mutation (SNP) | VAF 53/427 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.138); catalogued as rs1294176009; called by muse, mutect2, varscan2
- PCNX3 | c.4912G>A p.V1638I | Missense Mutation (SNP) | VAF 80/455 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs547456802; called by muse, mutect2, varscan2
- RANBP3 | c.656G>T p.S219I | Missense Mutation (SNP) | VAF 48/430 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.296); catalogued as rs776725293; called by muse, mutect2, varscan2
- RFX5 | c.116+1G>A p.X39_splice | Splice Site (SNP) | VAF 22/240 reads (9%) | catalogued as rs972632936, COSV51838069; called by muse, mutect2
- RTL1 | c.3514C>T p.R1172C | Missense Mutation (SNP) | VAF 68/522 reads (13%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs561030751, COSV101128114; called by muse, mutect2, varscan2
- SCYL1 | c.1787C>T p.T596I | Missense Mutation (SNP) | VAF 53/461 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs1341531841; called by muse, mutect2, varscan2
- SEMA5A | c.3025G>A p.V1009I | Missense Mutation (SNP) | VAF 66/492 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs376772698; called by muse, mutect2, varscan2
- SEMA7A | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 35/313 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.033); catalogued as rs774736648; called by muse, mutect2, varscan2
- SERGEF | c.164del p.T55Kfs*21 | Frame Shift Del (DEL) | VAF 62/367 reads (17%) | catalogued as rs749299415; called by mutect2, pindel, varscan2
- SPEF2 | c.226C>A p.Q76K | Missense Mutation (SNP) | VAF 48/522 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.93); catalogued as COSV56796178, COSV99213995; called by muse, mutect2
- SS18L1 | c.860C>T p.T287M | Missense Mutation (SNP) | VAF 56/521 reads (11%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.828); catalogued as rs759619267; called by muse, mutect2
- TAF6 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 41/404 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs1430659861; called by muse, mutect2, varscan2
- TATDN2 | c.2141G>T p.R714L | Missense Mutation (SNP) | VAF 39/251 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV55053006; called by muse, mutect2, varscan2
- TICAM1 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 91/528 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376914657; called by muse, mutect2, varscan2
- TIE1 | c.1781G>A p.R594Q | Missense Mutation (SNP) | VAF 91/575 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0.015); catalogued as rs776717207; called by muse, mutect2, varscan2
- TNK1 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 61/416 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.181); catalogued as rs374420688; called by muse, mutect2, varscan2
- TNXB | c.9126G>T p.E3042D (on ENST00000647633; = p.E2795D on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 89/662 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.108); catalogued as rs1450052639; called by muse, varscan2
- TTN | c.7756dup p.I2586Nfs*3 (on ENST00000591111; = p.I2540Nfs*3 on NM_003319.4) | Frame Shift Ins (INS) | VAF 30/292 reads (10%) | catalogued as rs1553999983; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- ZC3H11B | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 34/304 reads (11%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs1475310204; called by muse, mutect2, varscan2
- ZFHX4 | c.3528G>T p.E1176D | Missense Mutation (SNP) | VAF 32/343 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.116); catalogued as COSV50532002; called by muse, mutect2
- BCOR | c.4815_4818del p.C1606Nfs*11 (on ENST00000378444 / NM_001123385.2; = p.C1572Nfs*11 on NM_017745.6) | Frame Shift Del (DEL) | VAF 54/225 reads (24%) | called by mutect2, pindel, varscan2
- CAND2 | c.2143G>T p.V715L (on ENST00000456430 / NM_001162499.2; = p.V622L on NM_012298.3) | Missense Mutation (SNP) | VAF 81/533 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CASZ1 | c.4772A>G p.H1591R | Missense Mutation (SNP) | VAF 89/513 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CEP350 | c.7840G>A p.E2614K | Missense Mutation (SNP) | VAF 41/343 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- CLNK | c.633C>T p.V211= | Splice Region (SNP) | VAF 12/182 reads (7%) | called by muse, mutect2
- CNTNAP2 | c.1342T>A p.S448T | Missense Mutation (SNP) | VAF 37/343 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.076); called by muse, mutect2
- DEPP1 | c.311_319del p.P104_W107delinsR | In Frame Del (DEL) | VAF 62/541 reads (11%) | called by mutect2, pindel, varscan2
- DISC1 | c.1372C>A p.L458I | Missense Mutation (SNP) | VAF 51/366 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EIF3B | c.595C>G p.R199G | Missense Mutation (SNP) | VAF 64/511 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- FGF14 | c.101G>T p.C34F | Missense Mutation (SNP) | VAF 50/453 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.367); called by mutect2, varscan2
- GALNT18 | c.503C>A p.S168* | Nonsense Mutation (SNP) | VAF 64/442 reads (14%) | called by muse, varscan2
- GAS2L1 | c.44G>A p.S15N | Missense Mutation (SNP) | VAF 79/515 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- IGHA1 | c.485G>A p.W162* | Nonsense Mutation (SNP) | VAF 77/480 reads (16%) | called by muse, mutect2, varscan2
- KCNH5 | c.532C>T p.H178Y | Missense Mutation (SNP) | VAF 30/266 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- KDM5B | c.4198C>G p.R1400G | Missense Mutation (SNP) | VAF 38/376 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.199); called by muse, mutect2
- LIFR | c.527T>C p.V176A | Missense Mutation (SNP) | VAF 41/313 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- MAPK3 | c.283T>G p.F95V | Missense Mutation (SNP) | VAF 54/456 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- MPRIP | c.2542C>G p.L848V | Missense Mutation (SNP) | VAF 61/481 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NAA30 | c.110G>A p.C37Y | Missense Mutation (SNP) | VAF 84/694 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PCDH9 | c.55G>A p.D19N | Missense Mutation (SNP) | VAF 58/388 reads (15%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- SCN7A | c.1709A>T p.N570I | Missense Mutation (SNP) | VAF 32/336 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- SEMA3E | c.394A>T p.T132S | Missense Mutation (SNP) | VAF 52/578 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.078); called by muse, mutect2
- SP100 | c.1921A>G p.R641G | Missense Mutation (SNP) | VAF 55/390 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- TENM3 | c.6105T>G p.N2035K | Missense Mutation (SNP) | VAF 61/485 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- TMEM229A | c.751G>A p.G251S | Missense Mutation (SNP) | VAF 25/750 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- TRIM42 | c.91T>A p.F31I | Missense Mutation (SNP) | VAF 53/446 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- ZFR2 | c.585C>A p.C195* | Nonsense Mutation (SNP) | VAF 61/424 reads (14%) | called by muse, mutect2, varscan2
- ACE | c.2802G>T p.L934= | Silent (SNP) | VAF 52/387 reads (13%) | called by muse, mutect2, varscan2
- CARMIL2 | c.2733G>A p.P911= | Silent (SNP) | VAF 54/560 reads (10%) | catalogued as rs762685250, COSV58023164; called by muse, mutect2
- COBL | c.2529C>T p.H843= | Silent (SNP) | VAF 204/760 reads (27%) | catalogued as rs1417308359, COSV99473157; called by muse, mutect2, varscan2
- DCAF12L1 | c.540C>A p.P180= | Silent (SNP) | VAF 89/390 reads (23%) | catalogued as COSV64422501; called by muse, mutect2, varscan2
- DSCAML1 | c.5133G>A p.Q1711= (on ENST00000321322; = p.Q1651= on NM_020693.4) | Silent (SNP) | VAF 53/420 reads (13%) | called by muse, mutect2, varscan2
- GLI3 | c.2637G>A p.A879= | Silent (SNP) | VAF 133/613 reads (22%) | catalogued as COSV67895422; called by muse, mutect2, varscan2
- HOXD4 | c.102C>T p.A34= | Silent (SNP) | VAF 75/560 reads (13%) | called by muse, mutect2, varscan2
- HSP90B1 | c.2076G>A p.P692= | Silent (SNP) | VAF 25/233 reads (11%) | catalogued as rs771669006, COSV55358077; called by muse, mutect2, varscan2
- MAGEA10 | c.1080C>T p.S360= | Silent (SNP) | VAF 56/225 reads (25%) | catalogued as rs138141548; called by muse, mutect2, varscan2
- MKNK1 | c.1218C>T p.N406= | Silent (SNP) | VAF 44/561 reads (8%) | catalogued as rs752571512, COSV100361464; called by muse, mutect2
- MMP19 | c.453G>A p.A151= | Silent (SNP) | VAF 99/462 reads (21%) | catalogued as rs768729991; called by muse, mutect2, varscan2
- MTUS2 | c.2385C>T p.S795= | Silent (SNP) | VAF 51/400 reads (13%) | catalogued as rs749268070, COSV70915839, COSV70917454; called by muse, mutect2, varscan2
- MYF5 | c.462G>A p.S154= | Silent (SNP) | VAF 122/390 reads (31%) | catalogued as rs751777341, COSV57354383; called by muse, mutect2, varscan2
- MYH1 | c.5742T>C p.A1914= | Silent (SNP) | VAF 42/498 reads (8%) | called by muse, mutect2
- NOTCH4 | c.5382G>A p.E1794= | Silent (SNP) | VAF 64/628 reads (10%) | catalogued as COSV66682632; called by muse, varscan2
- SALL1 | c.1161G>A p.A387= | Silent (SNP) | VAF 74/502 reads (15%) | catalogued as rs200170000; called by muse, mutect2, varscan2
- SFTPB | c.846C>T p.S282= | Silent (SNP) | VAF 38/305 reads (12%) | catalogued as rs1234243117, COSV60893442; called by muse, mutect2, varscan2
- TRIM59 | c.1135C>T p.L379= | Silent (SNP) | VAF 27/275 reads (10%) | catalogued as COSV59087015; called by muse, mutect2, varscan2
- TRPA1 | c.627T>A p.G209= | Silent (SNP) | VAF 33/282 reads (12%) | called by muse, mutect2, varscan2
- DUSP5 | c.-1C>T | 5'UTR (SNP) | VAF 13/229 reads (6%) | called by muse, mutect2
- KIAA1328 | c.1232+16620G>A | Intron (SNP) | VAF 39/251 reads (16%) | called by muse, mutect2, varscan2
- LBH | c.26+415C>T | Intron (SNP) | VAF 31/286 reads (11%) | called by muse, mutect2, varscan2
- RAVER1 | c.1431+358C>T | Intron (SNP) | VAF 63/512 reads (12%) | called by muse, mutect2, varscan2
